Somatic mutation profile of tumor specimen TARGET-10-PATLGU-09A (aliquot TARGET-10-PATLGU-09A-01D) from TARGET case TARGET-10-PATLGU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,578 days).
Specimen TARGET-10-PATLGU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06fbb7ee-17ae-4421-9fbc-20bd8577be34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATLGU-10A (Blood Derived Normal), aliquot TARGET-10-PATLGU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f936376e-6c16-4513-8882-6393381e39c4

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Intron 3, Frame Shift Del 2, RNA 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.10021G>A p.D3341N | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs199571253; called by muse, mutect2, varscan2
- CCNB3 | c.2474C>A p.A825D | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT tolerated (0.63); PolyPhen benign (0.036); catalogued as COSV52075148; called by muse, mutect2, varscan2
- DNM2 | c.2377_2378del p.L793Dfs*30 (on ENST00000355667 / NM_001005360.3; = p.L789Dfs*30 on NM_004945.3) | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | catalogued as COSV53033511; called by mutect2, pindel, varscan2
- FLNB | c.5065C>T p.R1689C | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762205881, COSV55883400; called by muse, mutect2, varscan2
- NOTCH1 | c.4790G>T p.S1597I | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1564190486, COSV53061784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4C16 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199938003, COSV58942583; called by muse, mutect2, varscan2
- PRKACG | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1305720944, COSV55250621; called by muse, mutect2, varscan2
- TMTC2 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as rs766174631, COSV58268660, COSV58273021; called by muse, mutect2, varscan2
- VEGFB | c.243C>A p.C81* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV58537093; called by muse, mutect2
- ADORA2B | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by mutect2, varscan2
- GATAD1 | c.582C>A p.S194R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- NUCB2 | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHF6 | c.665del p.N222Mfs*57 (on ENST00000332070 / NM_032458.3; = p.N223Mfs*70 on NM_032335.3) | Frame Shift Del (DEL) | VAF 61/103 reads (59%) | called by mutect2, pindel, varscan2
- RECQL4 | c.3241G>T p.A1081S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); called by muse, mutect2
- TET3 | c.3933C>A p.S1311R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by mutect2, varscan2
- THOC5 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLX3 | c.445A>T p.T149S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TLX3 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- USP9X | c.3696_3697insCCTT p.M1233Pfs*4 | Frame Shift Ins (INS) | VAF 24/27 reads (89%) | called by mutect2, pindel, varscan2
- YWHAZ | c.78G>T p.M26I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.529); called by muse, varscan2
- ELOVL7 | c.210G>T p.T70= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs373897782; called by mutect2, varscan2
- NCKAP5 | c.3870C>T p.P1290= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- PTPRF | c.1344C>A p.R448= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- SPATS2 | c.114G>A p.A38= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs374810178, COSV100423745; called by muse, mutect2, varscan2
- CFLAR | c.711+23dup | Intron (INS) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- ENO2 | c.1068-20A>G | Intron (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- HDAC11 | c.552+13C>A | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- ZNF503-AS2 | n.723C>A | RNA (SNP) | VAF 4/29 reads (14%) | called by muse, varscan2
